Somatic mutation profile of tumor specimen TCGA-WB-A81D-01A (aliquot TCGA-WB-A81D-01A-11D-A35I-08) from TCGA case TCGA-WB-A81D, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 82.4 years (30,101 days).
Specimen TCGA-WB-A81D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b3a66ff-da14-45f3-b0dd-b2f3c67dcef7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WB-A81D-10A (Blood Derived Normal), aliquot TCGA-WB-A81D-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/527e0c96-103d-465f-88bf-4c3d97eb635c

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 10, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRTAC1 | c.1351C>T p.R451C | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.642); catalogued as rs576681356, COSV53997998; called by muse, mutect2, varscan2
- PARD3 | c.3587C>T p.S1196L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as rs1455847227; called by muse, mutect2, varscan2
- PCDHB12 | c.1334A>G p.N445S | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1554286860; called by muse, mutect2
- SUPT20H | c.1373G>A p.G458D (on ENST00000350612 / NM_001014286.3; = p.G459D on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.835); catalogued as rs868002952, COSV62248855; called by muse, mutect2
- ATP8B1 | c.1916C>G p.T639R | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNA1H | c.4289T>C p.I1430T | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MUC5B | c.11236G>C p.A3746P | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.589); called by muse, varscan2
- RBP4 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TDGF1 | c.107T>C p.F36S | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TVP23C | c.98A>T p.H33L | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- CHL1 | c.456A>G p.P152= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as rs146408628; called by muse, mutect2, varscan2
- PRKX | c.639C>T p.P213= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs750781693, COSV99468142; called by muse, varscan2
- RHOBTB1 | c.645A>G p.Q215= | Silent (SNP) | VAF 15/190 reads (8%) | called by muse, mutect2
- SLC49A4 | c.501A>G p.P167= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as rs572207932; called by muse, mutect2, varscan2
